Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5LR, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5LR-01A (Primary Tumor).

ICD-O-3
Carcinoma, adrenal cortical
8370/3

Site ① Adrenal Gland Cortex
C74.0

9/22/13

Procedure: Left adrenalectomy

Gross description: tumor is 96g; measuring 6.7 x 4.6cm.

Diagnosis: Adrenal cortical carcinoma. Weiss score = 7.

stP-A Discrepancy		

Source: NCI Genomic Data Commons file a2f0a1c5-db0c-48fe-857e-6652b5cfa447 (TCGA-OR-A5LR.A1C555F3-4513-45C6-9A39-968902130B94.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).